Gene-level copy-number profile of tumor specimen TCGA-DA-A95Z-06A from TCGA case TCGA-DA-A95Z, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 87.2 years (31,837 days).
Specimen TCGA-DA-A95Z-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.4c3bc020-780f-46fa-b37f-7edbfd4dcc36.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DA-A95Z-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8e42600b-7fd0-475c-b761-a51a801de356

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 8,542; copy number 3: 28,119; copy number 4: 14,709; copy number 5: 4,111; copy number 6: 2,178; copy number 7: 895; copy number 8: 1,256; copy number 9: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DA-A95Z-06A-11D-A371-01): tumor purity 0.8, ploidy 3.47, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,157 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:86,216,785–159,233,377, 1,463 genes, copy number 7–8 (broad region; genes not listed).
- chr8:13,083,361–31,546,735, 351 genes, copy number 7 (broad region; genes not listed).
- chr8:53,388,701–53,540,300, 7 genes, copy number 8: AC131902.1, AC022034.3, AC131902.2, AC022034.1, AC022034.4, AC022034.2, MAPK6P1.
- chr20:12,243,308–12,952,519, 6 genes, copy number 9 (within-gene range 3–9): AL109838.1, AL136460.1, PA2G4P2, LINC01722, AL078623.1, AL133331.1.
- chr22:15,290,718–20,408,461, 234 genes, copy number 7 (broad region; genes not listed).
- chr22:43,400,331–48,023,004, 96 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
